TARGET case TARGET-30-PANATP — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/f9fda946-9231-5c55-90ef-6fc00d5dccf7

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 4.5 years (1,631 days); Year of diagnosis: 2004; Days to last follow up: 357 days; INSS stage: Stage 4.

Biospecimens (1 sample)
- Sample TARGET-30-PANATP-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
